Somatic mutation profile of tumor specimen MP2PRT-PASRHS-TMP1-A (aliquot MP2PRT-PASRHS-TMP1-A-1-0-D-A80I-36) from MP2PRT case MP2PRT-PASRHS, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.3 years (2,653 days).
Specimen MP2PRT-PASRHS-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8a91ae9d-4d41-4040-be91-181b3d2c90ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASRHS-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASRHS-NB1-A-1-0-D-A80I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a5a540b5-ee31-402c-b9b3-05fe75cade27

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.5039_5041del p.S1680del | In Frame Del (DEL) | VAF 49/460 reads (11%) | hotspot (GDC flag); catalogued as rs587783502; called by pindel, varscan2
- GJD4 | c.661C>T p.R221W | Missense Mutation (SNP) | VAF 59/832 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs764218355, COSV58703484; called by muse, mutect2
- PDCD6 | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 103/301 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs149412009; called by muse, mutect2, varscan2
- SEMA3A | c.2189G>A p.R730Q | Missense Mutation (SNP) | VAF 113/303 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.272); catalogued as rs318240752, CM149886; ClinVar: not provided; called by muse, mutect2
- PABPC4L | c.92G>T p.S31I | Missense Mutation (SNP) | VAF 120/448 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- PCDH1 | c.2156C>G p.S719C | Missense Mutation (SNP) | VAF 148/440 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- DNAH9 | c.12633C>T p.D4211= | Silent (SNP) | VAF 99/279 reads (35%) | catalogued as rs200349675, COSV52340958; called by muse, mutect2, varscan2
- RBP4 | c.192C>T p.S64= | Silent (SNP) | VAF 20/730 reads (3%) | catalogued as COSV101012287; called by muse, mutect2
